Somatic mutation profile of tumor specimen MMRF_2272_1_BM_CD138pos (aliquot MMRF_2272_1_BM_CD138pos_T1_KHS5U_L09537) from MMRF case MMRF_2272, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.3 years (20,936 days).
Specimen MMRF_2272_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1205f118-1e1d-407c-809f-869b1ea4cf79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2272_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2272_1_PB_CD3pos_C3_KHS5U_L09538; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f6fa5b7-bae2-4596-8b2f-d903efe1c16e

The open-access MAF lists 56 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 18, Missense Mutation 14, Intron 8, Nonsense Mutation 4, Silent 4, 5'UTR 4, 5'Flank 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*676C>A | 3'UTR (SNP) | VAF 34/183 reads (19%) | catalogued as rs28933068, CM950474, CM950475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFATC4 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 7/143 reads (5%) | catalogued as COSV51605150; called by muse, mutect2
- PDX1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.894); catalogued as rs913578374; called by muse, mutect2, varscan2
- RAB3A | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 35/340 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs1371159424, COSV99717968; called by muse, mutect2, varscan2
- TNK1 | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs771022480; called by muse, mutect2, varscan2
- ACACA | c.6364C>T p.Q2122* | Nonsense Mutation (SNP) | VAF 29/148 reads (20%) | called by muse, mutect2, varscan2
- CLEC11A | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 19/344 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); called by muse, mutect2
- CORO2B | c.603C>A p.D201E | Missense Mutation (SNP) | VAF 21/345 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ERI2 | c.877G>T p.V293F | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.246); called by muse, mutect2
- LAMB1 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- LRP12 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 32/674 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- MAPK15 | c.1441G>T p.V481L | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYO5A | c.1000C>A p.H334N | Missense Mutation (SNP) | VAF 29/354 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- NAV3 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 24/320 reads (8%) | called by muse, mutect2
- NELFCD | c.1273C>G p.Q425E (on ENST00000602795; = p.Q407E on NM_198976.4) | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); called by muse, mutect2
- STARD7 | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.716); called by mutect2, varscan2
- STRA6 | c.183C>G p.I61M | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- SV2A | c.1594G>T p.E532* | Nonsense Mutation (SNP) | VAF 70/130 reads (54%) | called by muse, mutect2, varscan2
- TEX48 | c.144G>C p.K48N | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ABHD16B | c.417C>T p.H139= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as rs1350366723, COSV53862339; called by muse, mutect2, varscan2
- C5 | c.2034G>A p.T678= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs1288625842; called by muse, mutect2, varscan2
- IGLV3-1 | c.51C>A p.S17= | Silent (SNP) | VAF 79/157 reads (50%) | catalogued as rs376572967; called by muse, varscan2
- PRDM9 | c.366G>A p.A122= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs766083673, COSV57008152, COSV57010953; called by muse, mutect2, varscan2
- BBS7 | c.2014+18G>T | Intron (SNP) | VAF 24/414 reads (6%) | called by muse, mutect2
- BEND2 | c.*265G>A | 3'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- C1QL3 | c.-324G>T | 5'UTR (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- C9orf152 | c.-223T>A | 5'UTR (SNP) | VAF 31/54 reads (57%) | called by muse, mutect2, varscan2
- CCDC7 | c.2123-10277C>T | Intron (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- CHRM3 | c.*4648C>T | 3'UTR (SNP) | VAF 23/162 reads (14%) | called by muse, mutect2, varscan2
- CHRNA5 | c.*236G>A | 3'UTR (SNP) | VAF 13/154 reads (8%) | called by muse, mutect2
- CTSE | c.*345C>T | 3'UTR (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- CYP2G1P | n.2208C>T | RNA (SNP) | VAF 30/142 reads (21%) | called by muse, mutect2, varscan2
- DCTN4 | c.*942del | 3'UTR (DEL) | VAF 9/76 reads (12%) | called by mutect2, pindel, varscan2
- DLC1 | c.*1249A>T | 3'UTR (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- DLG1 | c.-31-212C>T | Intron (SNP) | VAF 24/88 reads (27%) | catalogued as rs887376621; called by muse, mutect2, varscan2
- ESRRG | chr1:216723462 G>A | 5'Flank (SNP) | VAF 30/233 reads (13%) | catalogued as rs946950824; called by muse, mutect2, varscan2
- GLIS3 | c.*1062G>T | 3'UTR (SNP) | VAF 20/162 reads (12%) | called by mutect2, varscan2
- HOXA13 | c.*2003A>G | 3'UTR (SNP) | VAF 17/175 reads (10%) | called by muse, mutect2
- IPO8 | c.84+509G>T | Intron (SNP) | VAF 59/424 reads (14%) | called by muse, mutect2, varscan2
- KCTD12 | c.-113C>G | 5'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as COSV58524184; called by muse, mutect2
- LINC01549 | n.390G>A | RNA (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- MRPL50 | c.*1174G>A | 3'UTR (SNP) | VAF 30/208 reads (14%) | called by muse, mutect2, varscan2
- NLN | c.*3211_*3214del | 3'UTR (DEL) | VAF 19/41 reads (46%) | called by mutect2, pindel, varscan2
- PITPNM1 | c.*185dup | 3'UTR (INS) | VAF 32/80 reads (40%) | catalogued as rs1213334361; called by pindel, varscan2
- PRSS22 | c.*194G>T | 3'UTR (SNP) | VAF 19/33 reads (58%) | catalogued as rs1299843436; called by muse, mutect2, varscan2
- RASSF6 | c.*187A>T | 3'UTR (SNP) | VAF 12/100 reads (12%) | catalogued as COSV100274880; called by muse, mutect2, varscan2
- RNASEH2A | chr19:12806526 A>T | 5'Flank (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- SCAF8 | c.-469C>G | 5'UTR (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- SHISA7 | c.*1439T>A | 3'UTR (SNP) | VAF 22/348 reads (6%) | called by muse, mutect2
- SLC44A1 | c.*3441G>A | 3'UTR (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- TAB2 | c.*837T>G | 3'UTR (SNP) | VAF 42/90 reads (47%) | called by muse, varscan2
- WDR75 | c.217-31A>T | Intron (SNP) | VAF 24/62 reads (39%) | catalogued as rs1180102340; called by muse, mutect2, varscan2
- ZFYVE21 | c.190-250G>A | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2
- ZGRF1 | c.102+1932T>G | Intron (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- ZNF396 | c.562+130G>A | Intron (SNP) | VAF 7/50 reads (14%) | catalogued as rs928878102; called by muse, mutect2
- ZNF415 | c.*13T>C | 3'UTR (SNP) | VAF 20/220 reads (9%) | catalogued as rs757554565; called by muse, mutect2
